Surgical pathology report (de-identified scan), TCGA case TCGA-ZF-AA4N, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Sheffield, specimen TCGA-ZF-AA4N-01A (Primary Tumor).

Histopathology

Specimen Comments

SPECIMEN

Bladder tumour.

CLINICAL DETAILS

New TCC. Clinically muscle invasive and ? originating from a diverticulum.

Incomplete resection.

MACROSCOPY

2g of friable tissue chippings + blood clot.

MICROSCOPY

Sections show a poorly differentiated carcinoma with a solid growth pattern, invading muscularis propria. Laminated layers of keratin, indicating squamous differentiation, are present. Large areas of necrosis are present. No transitional urothelium has been identified but several strips of non-dysplastic squamous epithelium are present. No vascular invasion identified.

The features are of a high grade carcinoma but it is not possible to determine definitively whether this is transitional carcinoma showing squamous differentiation or a primary squamous carcinoma.

SUMMARY

Poorly differentiated carcinoma G3 pT2.

Ref:

Pathologists -

TSS

Pathologist could not differentiate between squamous differentiation and transitional. Case will be coded as 'NOS' and will be annotated as such.

hw 11/13/14

ICD-0-3

Carcinoma, NOS 8010/3

Site: bladder, NOS C67.9

Source: NCI Genomic Data Commons file ba6344b7-03cf-4913-aa0b-c0bcfdc7fb59 (TCGA-ZF-AA4N.2330755B-EBE4-46DA-ABAB-A240CD849F36.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).